Somatic mutation profile of tumor specimen ALCH-B1HF-TTP1-A (aliquot ALCH-B1HF-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1HF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 74.8 years (27,320 days).
Specimen ALCH-B1HF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1db803fb-3b91-4ab3-ab7b-43b30c955fbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1HF-NB1-A (Blood Derived Normal), aliquot ALCH-B1HF-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9212929a-0483-45ec-9134-6f8011434746

The open-access MAF lists 332 somatic variants for this specimen: 207 protein-altering or splice-affecting, 88 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 88, Nonsense Mutation 17, Intron 16, 5'Flank 6, RNA 5, 3'Flank 4, Frame Shift Del 3, Splice Site 3, 3'UTR 3, 5'UTR 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 193/727 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- FOXL2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 43/320 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM082718, COSV57725966, COSV57728681; called by mutect2, varscan2
- ABHD4 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 91/415 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs781452282, COSV53529515; called by muse, mutect2, varscan2
- ANGPTL1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751800080; called by muse, mutect2, varscan2
- ANKRD65 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 92/389 reads (24%) | catalogued as rs1023854707, COSV99068730; called by muse, mutect2, varscan2
- BEND2 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs1366859789; called by muse, mutect2, varscan2
- BUD13 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs151030369; called by muse, mutect2, varscan2
- C1QB | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59245279; called by muse, mutect2, varscan2
- C9 | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 37/537 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV99661559; called by muse, mutect2
- CFHR4 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52228832; called by muse, mutect2, varscan2
- CNTNAP2 | c.847C>A p.R283S | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62203066; called by muse, mutect2, varscan2
- COMMD8 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67500327; called by muse, mutect2, varscan2
- DMD | c.7409C>A p.P2470H | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100627889; called by muse, mutect2, varscan2
- DPPA4 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 42/447 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59511837; called by muse, mutect2
- DSTYK | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.039); catalogued as rs1035843168; called by muse, mutect2, varscan2
- DYNC2LI1 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461829740; called by muse, mutect2, varscan2
- DYSF | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs771694976; called by muse, mutect2, varscan2
- ELFN1 | c.1600C>G p.P534A | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV70036663; called by muse, mutect2, varscan2
- FLAD1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV52698672; called by muse, mutect2
- GABRG2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62718083; called by muse, mutect2, varscan2
- GBP3 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1435199280; called by muse, mutect2, varscan2
- HBB | c.270T>A p.S90R | Missense Mutation (SNP) | VAF 91/623 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1110878; called by muse, mutect2, varscan2
- HEMGN | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV52326774; called by muse, mutect2, varscan2
- HOXB6 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs774958196; called by muse, mutect2, varscan2
- HTT | c.9349G>A p.E3117K | Missense Mutation (SNP) | VAF 108/553 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as rs1246746104, COSV61856906; called by muse, mutect2, varscan2
- IGKV6-21 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 27/385 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as rs747142565; called by muse, mutect2
- IGSF8 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs138031652; called by muse, mutect2, varscan2
- KCNQ2 | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 118/386 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM135158; called by muse, mutect2, varscan2
- KCNT2 | c.1903G>T p.V635F | Missense Mutation (SNP) | VAF 129/400 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as rs760051450, COSV54090510; called by muse, mutect2, varscan2
- KLHL1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 124/521 reads (24%) | catalogued as COSV64785647; called by muse, mutect2, varscan2
- KLHL34 | c.1739A>G p.K580R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.1); catalogued as rs146742477; called by muse, mutect2, varscan2
- LENG8 | c.1926G>C p.Q642H | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418097; called by muse, mutect2, varscan2
- LUZP4 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV64219623; called by muse, mutect2, varscan2
- MAD1L1 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV56230294; called by muse, mutect2, varscan2
- MICAL3 | c.4954C>T p.R1652C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs372785371; called by muse, mutect2, varscan2
- MIOX | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs1345608531, COSV53313420, COSV99327115; called by muse, mutect2, varscan2
- NACAD | c.1316G>C p.G439A | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.084); catalogued as COSV71989547; called by muse, mutect2
- NCKAP5 | c.1398G>C p.K466N | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV104399377, COSV58436257; called by muse, mutect2, varscan2
- NLGN4X | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as rs886044072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOP58 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs1216567894; called by muse, mutect2, varscan2
- NUP160 | c.4301G>A p.R1434Q | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.704); catalogued as rs761317101, COSV101021602, COSV65855944; called by muse, mutect2
- OXTR | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs752877652; called by muse, mutect2, varscan2
- PCDHGB3 | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99548922; called by muse, mutect2, varscan2
- PCM1 | c.3376A>G p.I1126V | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs773610626; called by muse, mutect2, varscan2
- PDLIM4 | c.32C>A p.S11* | Nonsense Mutation (SNP) | VAF 50/208 reads (24%) | catalogued as COSV53804681; called by muse, varscan2
- PER1 | c.2214G>T p.E738D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs868352607; called by muse, varscan2
- PLG | c.2051C>G p.A684G | Missense Mutation (SNP) | VAF 97/446 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV57515910; called by muse, mutect2, varscan2
- POM121L12 | c.369del p.L124Cfs*14 | Frame Shift Del (DEL) | VAF 98/306 reads (32%) | catalogued as rs765688315, COSV68693949; called by mutect2, varscan2
- POTEF | c.3143C>T p.S1048L | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as rs1389528317; called by mutect2, varscan2
- PRUNE1 | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 119/541 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as rs866471269; called by muse, mutect2, varscan2
- RBP3 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 345/711 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782455367; called by muse, mutect2, varscan2
- REXO1 | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs1376541920; called by muse, mutect2, varscan2
- RGPD3 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 50/559 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as COSV100449956, COSV58747491; called by muse, mutect2, varscan2
- RYR2 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100769684; called by muse, mutect2, varscan2
- SAMD9L | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59084502; called by muse, mutect2, varscan2
- SEC23B | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 150/795 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as CM094614; called by muse, mutect2, varscan2
- SUMF2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1361736647, COSV51904211; called by muse, mutect2, varscan2
- SUZ12 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100497092; called by muse, mutect2, varscan2
- SYNPO2 | c.2484C>G p.F828L | Missense Mutation (SNP) | VAF 81/368 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV61110133; called by muse, mutect2, varscan2
- TBX2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 78/424 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329600365; called by muse, varscan2
- TMEM47 | c.512G>C p.C171S | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV99328082; called by muse, mutect2, varscan2
- TNFSF14 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV55591756; called by muse, mutect2, varscan2
- TP53 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as rs1555526581, CM013441, COSV52748282, COSV52919256, COSV53146850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP3 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478574249, COSV56184906; called by muse, mutect2
- UBC | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 101/972 reads (10%) | catalogued as rs1229462757, COSV100299029; called by muse, mutect2, varscan2
- UBR5 | c.5380C>G p.Q1794E | Missense Mutation (SNP) | VAF 72/560 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1236838631; called by muse, mutect2, varscan2
- USP29 | c.1857G>T p.Q619H | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.362); catalogued as COSV54143502; called by muse, mutect2, varscan2
- ZFPM2 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65872487; called by muse, mutect2, varscan2
- ZNF536 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs762646976, COSV62820064, COSV62833089; called by muse, mutect2, varscan2
- ZNF678 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.557); catalogued as rs1476324407; called by muse, mutect2
- ZSCAN10 | c.32G>A p.R11Q (on ENST00000252463; = p.R66Q on NM_032805.3) | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs770143632; called by muse, mutect2, varscan2
- ABCC5 | c.3698A>C p.K1233T | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.2000T>A p.I667N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ALDH3A1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ALYREF | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ANK2 | c.7903G>T p.D2635Y | Missense Mutation (SNP) | VAF 20/549 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- ANK3 | c.8374G>C p.E2792Q | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1771_1782+30del p.X591_splice | Splice Site (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel
- ARFIP2 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP39 | c.2779A>G p.T927A (on ENST00000276826 / NM_001308208.2; = p.T958A on NM_025251.2) | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARID5B | c.439A>G p.R147G | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ASB8 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 61/413 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ASH2L | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 96/346 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATE1 | c.254A>C p.Q85P | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- ATP2B3 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 76/177 reads (43%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- B3GNTL1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 117/419 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BCOR | c.1292C>T p.T431I | Missense Mutation (SNP) | VAF 49/740 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); called by muse, mutect2
- BLOC1S4 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- BMP8B | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 64/540 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2
- C17orf75 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 114/524 reads (22%) | called by muse, varscan2
- C6orf201 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CA2 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 125/499 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CAND1 | c.2039A>G p.N680S | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CBY3 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- CCDC110 | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- CCDC127 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- CCNYL1 | c.970G>C p.A324P (on ENST00000295414 / NM_001330218.2; = p.A254P on NM_152523.2) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDC27 | c.1073C>G p.T358R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CNKSR3 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CNTNAP4 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CPSF4L | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CSMD1 | c.8444C>A p.P2815H (on ENST00000520002; = p.P2814H on NM_033225.6) | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 38/699 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.183); called by muse, mutect2
- CXADR | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CYP11B2 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.251); called by muse, mutect2
- DBT | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- E2F5 | c.361T>A p.C121S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EDF1 | c.28A>T p.T10S | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ELFN1 | c.1044C>G p.F348L | Missense Mutation (SNP) | VAF 89/622 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EXD2 | c.469G>A p.A157T (on ENST00000312994 / NM_001193362.1; = p.A32T on NM_018199.3) | Missense Mutation (SNP) | VAF 21/719 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2
- FAM53C | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FBLN2 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- FEM1A | c.1092C>G p.I364M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- FLNC | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 92/533 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- FYB1 | c.1526C>A p.P509H | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GALT | c.329-3C>T | Splice Region (SNP) | VAF 102/673 reads (15%) | called by muse, mutect2, varscan2
- GPA33 | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 49/411 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GREB1L | c.673G>C p.G225R | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN2A | c.4156C>T p.P1386S | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- IQUB | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- IRF2BP1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KALRN | c.6626C>T p.A2209V (on ENST00000360013 / NM_001024660.4; = p.A512V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/272 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- KL | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 25/488 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.075); called by muse, mutect2
- KRT14 | c.1217C>G p.T406R | Missense Mutation (SNP) | VAF 57/1063 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- LGR6 | c.2858del p.G953Vfs*35 (on ENST00000367278 / NM_001017403.1; = p.G901Vfs*35 on NM_021636.3) | Frame Shift Del (DEL) | VAF 28/149 reads (19%) | called by mutect2, pindel
- LY6G6E | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 175/1872 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYPD6 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT tolerated (0.93); PolyPhen benign (0.006); called by muse, mutect2
- LYST | c.6586G>T p.G2196* | Nonsense Mutation (SNP) | VAF 79/687 reads (11%) | called by muse, mutect2, varscan2
- MED29 | c.450G>C p.Q150H (on ENST00000615911; = p.Q129H on NM_017592.4) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MMP17 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYH14 | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYOM2 | c.2044T>G p.F682V | Missense Mutation (SNP) | VAF 73/408 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NGLY1 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOL11 | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 28/167 reads (17%) | called by muse, mutect2, varscan2
- NRAP | c.4771_4773del p.K1591del (on ENST00000359988 / NM_001322945.2; = p.K1556del on NM_006175.4) | In Frame Del (DEL) | VAF 62/484 reads (13%) | called by pindel, varscan2
- NUDT19 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NYNRIN | c.1936C>G p.Q646E | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OCLN | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 20/140 reads (14%) | called by mutect2, varscan2
- OR2B6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- OR5B12 | c.218C>G p.S73* | Nonsense Mutation (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- OR5R1 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTC | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTOA | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- P4HA3 | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PAFAH1B2 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PBX2 | c.1041C>G p.F347L | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCDHB2 | c.785A>T p.Q262L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE8A | c.1837A>G p.S613G | Missense Mutation (SNP) | VAF 172/344 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- PKD1L3 | c.73A>T p.S25C | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLA2G4C | c.804G>T p.R268S | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLA2G4C | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PLCD1 | c.1597C>G p.Q533E | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.02); called by muse, mutect2
- POLQ | c.2230A>T p.N744Y | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- PPP1CB | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPP1R9B | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PRRC2C | c.1528G>A p.E510K (on ENST00000367742; = p.E508K on NM_015172.4) | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PSMB10 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by muse, mutect2
- RAD21 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RAPH1 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- RASSF3 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 132/286 reads (46%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RB1 | c.2250_2269delinsAT p.D750_N757delinsEY | In Frame Del (DEL) | VAF 56/170 reads (33%) | called by pindel, varscan2*
- RBP3 | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 286/548 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- RBP3 | c.1425C>G p.I475M | Missense Mutation (SNP) | VAF 92/178 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, varscan2
- RBP3 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 123/220 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RBP3 | c.2675C>G p.S892C | Missense Mutation (SNP) | VAF 217/457 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBPJ | c.126G>C p.M42I | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFC1 | c.3123_3124insT p.S1042* (on ENST00000381897 / NM_001363496.2; = p.S1041* on NM_002913.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/287 reads (11%) | called by mutect2, pindel*
- RGPD3 | c.5186G>C p.R1729T | Missense Mutation (SNP) | VAF 79/671 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RSPH10B | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- RYR2 | c.13126C>T p.L4376F | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SAP130 | c.2871G>T p.Q957H | Missense Mutation (SNP) | VAF 109/311 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCAP | c.2111G>C p.G704A | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, varscan2
- SH3KBP1 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 60/357 reads (17%) | called by muse, mutect2, varscan2
- SHARPIN | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SIPA1L1 | c.4429C>T p.Q1477* | Nonsense Mutation (SNP) | VAF 110/776 reads (14%) | called by muse, varscan2
- SMC1A | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 64/430 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SNX27 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- SOX21 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 98/680 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SPATA16 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SPATA31D4 | c.2750T>A p.I917K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPIRE2 | c.684G>C p.E228D | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STAG3 | c.2967C>G p.F989L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- STK38L | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- TAF3 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 41/254 reads (16%) | called by muse, mutect2, varscan2
- TASOR2 | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D22A | c.654G>C p.L218F | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- TCF4 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TCF4 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TDRD6 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TIMELESS | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- TOMM40 | c.197C>G p.S66* | Nonsense Mutation (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- TRAV12-1 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- TTC6 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TXK | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBTFL1 | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 29/413 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.846); called by muse, mutect2
- VPS37C | c.488_491del p.S163Wfs*35 | Frame Shift Del (DEL) | VAF 74/269 reads (28%) | called by mutect2, pindel, varscan2
- WDR11 | c.2516-1G>C p.X839_splice | Splice Site (SNP) | VAF 100/600 reads (17%) | called by muse, mutect2, varscan2
- WNT3A | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZFHX4 | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ZFYVE28 | c.254G>C p.C85S | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF286A | c.1369C>G p.Q457E | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- ZNF34 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 59/391 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ZNF521 | c.3847G>C p.D1283H | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF605 | c.1556A>T p.Q519L | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZNF606 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ZNF616 | c.140-2A>G p.X47_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- ADGRG4 | c.4605G>A p.V1535= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV54955980; called by muse, mutect2, varscan2
- ANO2 | c.2286A>G p.A762= (on ENST00000356134 / NM_001278597.3; = p.A766= on NM_001278596.3) | Silent (SNP) | VAF 21/292 reads (7%) | called by muse, mutect2
- ARHGDIG | c.492C>G p.V164= | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- ASTN1 | c.1623C>T p.G541= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV99921288; called by muse, mutect2, varscan2
- ATP2B3 | c.465C>T p.I155= | Silent (SNP) | VAF 73/172 reads (42%) | catalogued as rs782813423, COSV54861599; called by muse, mutect2, varscan2
- ATP7B | c.3381G>A p.L1127= | Silent (SNP) | VAF 113/485 reads (23%) | catalogued as rs587783311; ClinVar: benign; called by muse, mutect2, varscan2
- BDP1 | c.7335G>A p.Q2445= | Silent (SNP) | VAF 57/327 reads (17%) | catalogued as rs772623367, COSV62435881; called by muse, mutect2, varscan2
- CACNA1E | c.3348G>A p.Q1116= | Silent (SNP) | VAF 60/387 reads (16%) | called by muse, mutect2, varscan2
- CACNA1S | c.4297C>T p.L1433= | Silent (SNP) | VAF 34/290 reads (12%) | called by muse, varscan2
- CAMTA1 | c.1617C>T p.F539= | Silent (SNP) | VAF 69/379 reads (18%) | catalogued as rs759254917, COSV57916382; called by muse, mutect2, varscan2
- CD40 | c.27C>T p.V9= | Silent (SNP) | VAF 120/802 reads (15%) | called by muse, mutect2, varscan2
- CHADL | c.1275C>T p.S425= | Silent (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- CLK1 | c.1440G>A p.L480= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV58434135; called by muse, mutect2, varscan2
- CNOT1 | c.6435A>T p.P2145= | Silent (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2
- CYP26B1 | c.979C>A p.R327= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV99134223; called by muse, mutect2, varscan2
- DAB2IP | c.3129G>T p.A1043= (on ENST00000408936; = p.A1015= on NM_032552.3) | Silent (SNP) | VAF 150/383 reads (39%) | called by muse, mutect2, varscan2
- DGAT2 | c.435G>T p.V145= | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2
- DNAH17 | c.6063G>C p.L2021= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- DNAH17 | c.4971G>C p.L1657= | Silent (SNP) | VAF 23/172 reads (13%) | called by muse, mutect2, varscan2
- DNAH5 | c.8418C>T p.N2806= | Silent (SNP) | VAF 23/215 reads (11%) | catalogued as rs769684045; called by muse, mutect2, varscan2
- EFTUD2 | c.2481G>C p.L827= | Silent (SNP) | VAF 61/263 reads (23%) | called by muse, mutect2, varscan2
- ELFN1 | c.1278C>G p.L426= | Silent (SNP) | VAF 35/291 reads (12%) | catalogued as rs1203437990, COSV101300276; called by muse, mutect2, varscan2
- EXOC3 | c.360C>T p.F120= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1296407129; called by muse, mutect2
- FBXL6 | c.465G>T p.A155= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as rs371752698; called by muse, mutect2, varscan2
- FCGR3B | c.15C>G p.L5= | Silent (SNP) | VAF 39/453 reads (9%) | catalogued as COSV54212773; called by muse, mutect2
- GLYATL2 | c.884G>A p.*295= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- GPR158 | c.3234C>A p.G1078= | Silent (SNP) | VAF 144/515 reads (28%) | called by muse, mutect2, varscan2
- GTF3C3 | c.63C>T p.F21= | Silent (SNP) | VAF 62/326 reads (19%) | catalogued as COSV55831670; called by muse, mutect2, varscan2
- HAS3 | c.1443C>T p.L481= | Silent (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- HECW2 | c.3390A>T p.S1130= | Silent (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- IMMT | c.828A>T p.T276= | Silent (SNP) | VAF 114/422 reads (27%) | called by muse, mutect2, varscan2
- IRAK3 | c.621G>A p.K207= | Silent (SNP) | VAF 12/309 reads (4%) | called by muse, mutect2
- JMJD1C | c.3192C>T p.I1064= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1424784480; called by muse, mutect2, varscan2
- KIF24 | c.660G>A p.E220= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as rs547261080; called by muse, mutect2, varscan2
- KIF7 | c.3951C>T p.N1317= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- LCN8 | c.360G>C p.L120= (on ENST00000612714 / NM_001345934.1; = p.L97= on NM_178469.3) | Silent (SNP) | VAF 57/416 reads (14%) | called by muse, mutect2, varscan2
- LTBP1 | c.4221T>C p.F1407= (on ENST00000404816 / NM_206943.4; = p.F1081= on NM_000627.4) | Silent (SNP) | VAF 40/249 reads (16%) | called by muse, mutect2, varscan2
- MAEL | c.828T>C p.D276= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- MAFK | c.57G>A p.E19= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- MC2R | c.675C>G p.L225= | Silent (SNP) | VAF 74/378 reads (20%) | catalogued as COSV100563048; called by muse, mutect2, varscan2
- MCCC2 | c.465G>T p.R155= | Silent (SNP) | VAF 70/366 reads (19%) | catalogued as COSV100040349; called by muse, mutect2, varscan2
- MCRS1 | c.135G>A p.R45= | Silent (SNP) | VAF 33/245 reads (13%) | catalogued as rs763448109; called by muse, mutect2, varscan2
- MKX | c.315C>A p.L105= | Silent (SNP) | VAF 44/354 reads (12%) | called by muse, mutect2, varscan2
- MUC17 | c.2550T>G p.A850= | Silent (SNP) | VAF 114/361 reads (32%) | called by muse, mutect2, varscan2
- MYPOP | c.177C>T p.I59= | Silent (SNP) | VAF 56/337 reads (17%) | catalogued as rs1337098733, COSV59133009, COSV59134382; called by muse, mutect2, varscan2
- NANS | c.324C>T p.F108= | Silent (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- NFASC | c.477G>A p.T159= (on ENST00000339876 / NM_001378329.1; = p.T153= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/392 reads (16%) | catalogued as rs760241661, COSV58362609; called by muse, mutect2, varscan2
- OGDH | c.1278C>T p.L426= | Silent (SNP) | VAF 72/453 reads (16%) | catalogued as rs368814406; called by muse, mutect2, varscan2
- OR2L5 | c.297G>A p.Q99= | Silent (SNP) | VAF 17/323 reads (5%) | called by muse, mutect2
- OR2T34 | c.459C>T p.C153= | Silent (SNP) | VAF 53/162 reads (33%) | catalogued as COSV100170608; called by muse, mutect2, varscan2
- PCDHB15 | c.402T>A p.P134= | Silent (SNP) | VAF 44/237 reads (19%) | called by muse, mutect2, varscan2
- PDE10A | c.423G>A p.G141= | Silent (SNP) | VAF 37/285 reads (13%) | catalogued as rs373361582; called by muse, mutect2, varscan2
- PDIA2 | c.153C>T p.T51= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV51991347; called by muse, mutect2, varscan2
- PHF8 | c.1209C>T p.I403= (on ENST00000357988 / NM_001184896.1; = p.I367= on NM_015107.3) | Silent (SNP) | VAF 74/401 reads (18%) | called by muse, mutect2, varscan2
- PICALM | c.1590C>G p.L530= | Silent (SNP) | VAF 66/497 reads (13%) | catalogued as COSV62673326; called by muse, mutect2, varscan2
- PKD1 | c.4954C>T p.L1652= | Silent (SNP) | VAF 158/438 reads (36%) | catalogued as rs895882636; called by muse, mutect2, varscan2
- PLCB1 | c.409T>C p.L137= | Silent (SNP) | VAF 33/248 reads (13%) | catalogued as rs369124253; called by muse, mutect2, varscan2
- PNLIPRP1 | c.879C>T p.L293= | Silent (SNP) | VAF 39/267 reads (15%) | catalogued as rs1384815091; called by muse, mutect2, varscan2
- PTPRM | c.1245C>T p.L415= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs745313176; called by muse, mutect2, varscan2
- RBM48 | c.934C>T p.L312= | Silent (SNP) | VAF 16/251 reads (6%) | catalogued as COSV99720070; called by muse, mutect2
- RBP3 | c.1990C>T p.L664= | Silent (SNP) | VAF 198/415 reads (48%) | called by muse, varscan2
- RBP3 | c.2044C>T p.L682= | Silent (SNP) | VAF 246/556 reads (44%) | called by muse, varscan2
- RBP3 | c.2460C>G p.V820= | Silent (SNP) | VAF 456/969 reads (47%) | called by muse, mutect2, varscan2
- RET | c.1086C>G p.L362= | Silent (SNP) | VAF 252/806 reads (31%) | called by muse, varscan2
- RET | c.1230C>A p.L410= | Silent (SNP) | VAF 237/594 reads (40%) | catalogued as COSV60708374; called by muse, mutect2, varscan2
- RNF151 | c.609C>G p.L203= | Silent (SNP) | VAF 58/316 reads (18%) | catalogued as rs1273300149; called by muse, mutect2, varscan2
- SF3B3 | c.2925G>A p.K975= | Silent (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- SIKE1 | c.447A>G p.G149= | Silent (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- SLC30A10 | c.897C>T p.I299= | Silent (SNP) | VAF 47/333 reads (14%) | catalogued as COSV100751501; called by muse, mutect2, varscan2
- SLC4A3 | c.3630G>A p.S1210= | Silent (SNP) | VAF 78/285 reads (27%) | catalogued as rs375924981, COSV56098411; called by muse, mutect2, varscan2
- SUPT20H | c.597C>T p.L199= (on ENST00000350612 / NM_001014286.3; = p.L200= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/220 reads (18%) | catalogued as COSV100634630; called by muse, mutect2, varscan2
- SYNE2 | c.20652C>T p.P6884= | Silent (SNP) | VAF 138/489 reads (28%) | catalogued as COSV59940239; called by muse, mutect2, varscan2
- TBC1D30 | c.345C>G p.L115= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs772682393; called by muse, mutect2, varscan2
- TGM4 | c.1470C>T p.F490= | Silent (SNP) | VAF 93/482 reads (19%) | called by muse, mutect2, varscan2
- TMEM18 | c.111C>T p.L37= | Silent (SNP) | VAF 67/436 reads (15%) | called by muse, mutect2, varscan2
- TRIML1 | c.612G>A p.E204= | Silent (SNP) | VAF 51/399 reads (13%) | catalogued as rs150151923, COSV60197366; called by muse, mutect2, varscan2
- TSSC4 | c.822C>T p.H274= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99330151; called by muse, mutect2, varscan2
- TTN | c.90486C>T p.N30162= (on ENST00000591111; = p.N22738= on NM_003319.4) | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs727505040; ClinVar: likely benign; called by muse, mutect2
- URB2 | c.4158G>A p.L1386= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- VWF | c.5226C>T p.D1742= | Silent (SNP) | VAF 116/990 reads (12%) | catalogued as rs748715084, COSV54618295; called by mutect2, varscan2
- ZBED4 | c.378C>T p.I126= | Silent (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- ZBED4 | c.555C>T p.P185= | Silent (SNP) | VAF 16/41 reads (39%) | called by mutect2, varscan2
- ZDHHC5 | c.651C>T p.T217= | Silent (SNP) | VAF 37/353 reads (10%) | called by muse, mutect2, varscan2
- ZNF214 | c.858G>A p.Q286= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1477661884; called by muse, mutect2, varscan2
- ZNF430 | c.1227C>T p.G409= | Silent (SNP) | VAF 64/196 reads (33%) | called by muse, mutect2, varscan2
- ZNF536 | c.471C>A p.P157= | Silent (SNP) | VAF 69/435 reads (16%) | catalogued as COSV62835879, COSV62836698; called by muse, mutect2, varscan2
- ZNF544 | c.798G>A p.V266= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV54136201; called by muse, mutect2, varscan2
- ZPBP2 | c.378C>G p.V126= (on ENST00000348931 / NM_199321.3; = p.V104= on NM_198844.3) | Silent (SNP) | VAF 76/129 reads (59%) | catalogued as COSV62375649; called by muse, mutect2, varscan2
- AC004696.1 | n.22T>C | RNA (SNP) | VAF 73/352 reads (21%) | called by muse, mutect2, varscan2
- AC009053.1 | chr16:74334978 G>C | 3'Flank (SNP) | VAF 49/386 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845542 T>A | 5'Flank (SNP) | VAF 61/160 reads (38%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852432 C>A | 3'Flank (SNP) | VAF 88/197 reads (45%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1237A>T | Intron (SNP) | VAF 62/249 reads (25%) | called by muse, mutect2, varscan2
- ANXA8 | c.*17G>A | 3'UTR (SNP) | VAF 28/356 reads (8%) | called by muse, varscan2
- AP000769.3 | chr11:65503673 del TGTC | 5'Flank (DEL) | VAF 7/62 reads (11%) | catalogued as rs751652054; called by mutect2, pindel
- CLEC3A | c.226+948C>T | Intron (SNP) | VAF 11/185 reads (6%) | called by muse, mutect2
- COQ6 | c.299-23T>A | Intron (SNP) | VAF 266/603 reads (44%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*1221T>C | 3'UTR (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- CTBP2 | c.58+12391C>T | Intron (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- DNAJC4 | c.-410T>C | 5'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- FAM172BP | n.551A>G | RNA (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- FAM90A27P | n.653C>T | RNA (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- FUT8 | c.-326+206C>T | Intron (SNP) | VAF 66/353 reads (19%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-1019G>A | Intron (SNP) | VAF 17/214 reads (8%) | called by muse, mutect2
- GMPR2 | c.*195G>A | 3'UTR (SNP) | VAF 32/415 reads (8%) | called by muse, mutect2
- JAKMIP1 | chr4:6049850 A>T | 3'Flank (SNP) | VAF 27/296 reads (9%) | called by muse, mutect2
- JPH3 | c.2167-756C>T | Intron (SNP) | VAF 69/426 reads (16%) | catalogued as rs1255510171; called by muse, mutect2, varscan2
- JPH3 | chr16:87701863 G>A | 3'Flank (SNP) | VAF 27/161 reads (17%) | catalogued as rs1321772298; called by muse, mutect2, varscan2
- LILRB5 | c.1630-95G>A | Intron (SNP) | VAF 33/244 reads (14%) | called by muse, mutect2, varscan2
- LIMS1 | c.156+11C>G | Intron (SNP) | VAF 22/570 reads (4%) | called by muse, mutect2
- LRP5 | c.-15C>A | 5'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- MAML3 | c.468+18543A>G | Intron (SNP) | VAF 56/240 reads (23%) | called by muse, mutect2, varscan2
- MFSD1 | c.163+186C>G | Intron (SNP) | VAF 71/484 reads (15%) | called by muse, mutect2, varscan2
- MIR7-3 | chr19:4769703 G>A | 5'Flank (SNP) | VAF 40/217 reads (18%) | catalogued as rs28713481; called by muse, mutect2, varscan2
- MRGPRF | c.48+46G>A | Intron (SNP) | VAF 57/260 reads (22%) | catalogued as rs1339174821; called by muse, mutect2, varscan2
- PALLD | c.1965-12838C>A | Intron (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.838+72C>G | Intron (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158921 G>T | 5'Flank (SNP) | VAF 76/299 reads (25%) | catalogued as rs1243719010; called by muse, varscan2
- RNA5-8SP2 | chr16:34158922 T>C | 5'Flank (SNP) | VAF 76/302 reads (25%) | catalogued as rs1460786724; called by muse, varscan2
- RPP38 | chr10:15096524 G>A | 5'Flank (SNP) | VAF 54/216 reads (25%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13303C>T | Intron (SNP) | VAF 42/248 reads (17%) | catalogued as COSV99755801; called by muse, mutect2, varscan2
- SCOC-AS1 | n.6587G>C | RNA (SNP) | VAF 44/235 reads (19%) | called by muse, mutect2, varscan2
- SUGCT | c.1089+2766C>T | Intron (SNP) | VAF 18/313 reads (6%) | catalogued as COSV100002250; called by muse, mutect2
- TCAF2P1 | n.1183C>A | RNA (SNP) | VAF 34/387 reads (9%) | called by muse, mutect2, varscan2
- UCP2 | c.-15C>G | 5'UTR (SNP) | VAF 134/438 reads (31%) | called by muse, mutect2, varscan2
